Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6G-01A from TCGA case TCGA-VQ-AA6G, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,091 days).
Specimen TCGA-VQ-AA6G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e0acb35c-78a2-4556-bdad-58533a6e5fc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03aafacb-68ea-4242-bcc7-8792dfa4b483

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 9,081; copy number 2: 48,845; copy number 3: 994; copy number 4: 87; copy number 5: 170; copy number 6: 557; copy number 9: 44; copy number 13: 2; copy number 14: 1; copy number 17: 11; copy number 22: 3; copy number 42: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6G-01A-11D-A40Z-01): tumor purity 0.62, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr18:50,879,080–51,058,144, 4 genes (within-gene range 0–1): ME2, Y_RNA, ELAC1, AC091551.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 803 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,172,059–28,649,538, 150 genes, copy number 6 (broad region; genes not listed).
- chr6:28,888,832–29,681,155, 56 genes, copy number 6: ZNF90P2, HCG14, TRIM27, RNU6-930P, LINC01556, KRT18P1, RN7SL471P, HCG15, AL662791.1, ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1, AL645937.4, OR2J2, OR2J4P, AL645937.3, AL672167.1, OR2G1P, OR2U1P, OR2U2P, OR14J1, DDX6P1, OR5V1, OR12D3, OR12D2, OR12D1, OR11A1, OR10C1, AL645927.1, OR2H1, UBDP1, MAS1LP1, MAS1L, RPS17P1, LINC02829, LINC01015, GPR53P, OR2I1P, UBD, GABBR1, OR2H5P, TMEM183AP1, SNORD32B, RPL13AP, OR2H2, SUMO2P1, MOG, ZFP57.
- chr6:30,102,897–31,301,642, 86 genes, copy number 5 (broad region; genes not listed).
- chr6:33,999,972–36,733,184, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:37,815,777–54,485,850, 351 genes, copy number 6 (broad region; genes not listed).
- chr17:38,671,703–40,061,215, 76 genes, copy number 9–42 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
